Somatic mutation profile of tumor specimen TCGA-FG-A60L-01A (aliquot TCGA-FG-A60L-01A-12D-A31L-08) from TCGA case TCGA-FG-A60L, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 34.4 years (12,580 days).
Specimen TCGA-FG-A60L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a8984c2-e53c-4bfe-809c-c02a3f2219a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A60L-10A (Blood Derived Normal), aliquot TCGA-FG-A60L-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/643b6a88-9807-4ff9-9ab0-7580ed5c97ee

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.1709G>A p.R570Q (on ENST00000372530 / NM_001198934.2; = p.R527Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745844891, COSV55085418; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/71 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.920-11_920del p.X307_splice | Splice Site (DEL) | VAF 44/101 reads (44%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AMIGO2 | c.214A>G p.R72G | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.652); catalogued as COSV99873614; called by muse, mutect2, varscan2
- AP3M1 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100786711; called by muse, mutect2, varscan2
- CDH22 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV64837628; called by muse, mutect2, varscan2
- CENPB | c.607_608insA p.F203Yfs*184 | Frame Shift Ins (INS) | VAF 39/145 reads (27%) | catalogued as COSV100713450; called by mutect2, pindel, varscan2
- FGD5 | c.3941G>A p.R1314Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs369779761; called by mutect2, varscan2
- FGFBP1 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs1210336964, COSV99469050; called by muse, mutect2, varscan2
- GDPGP1 | c.187C>G p.L63V | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.204); catalogued as COSV100292066; called by muse, mutect2, varscan2
- KIF16B | c.2950G>T p.E984* | Nonsense Mutation (SNP) | VAF 62/181 reads (34%) | catalogued as rs1364099539, COSV61702485, COSV61706284; called by muse, mutect2, varscan2
- KRT71 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as COSV57290419; called by muse, mutect2, varscan2
- LIPG | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM092681, COSV54298577, COSV99724264; called by muse, mutect2, varscan2
- MYH11 | c.5095G>A p.A1699T | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as rs200410021; ClinVar: uncertain significance; called by muse, mutect2
- MYH2 | c.4459C>G p.L1487V | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as COSV55434460, COSV99820211; called by muse, mutect2, varscan2
- PTPRM | c.3733G>A p.A1245T | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100157500; called by muse, mutect2, varscan2
- SERPINA6 | c.401A>G p.D134G | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as COSV100448305; called by muse, mutect2, varscan2
- SHB | c.773G>C p.S258T | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV100891058; called by muse, mutect2, varscan2
- THBS2 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100827904; called by muse, mutect2, varscan2
- ZFP69B | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV64315280; called by muse, mutect2, varscan2
- ZNF689 | c.537C>G p.C179W | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54910372, COSV99788006; called by muse, mutect2, varscan2
- ECM1 | c.288C>A p.L96= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as COSV100681990, COSV100682249; called by muse, mutect2, varscan2
- PCDHB15 | c.1476G>A p.P492= | Silent (SNP) | VAF 66/239 reads (28%) | catalogued as rs1554292094, COSV99178942; called by muse, mutect2, varscan2
- PRDM15 | c.498C>T p.D166= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs773784617, COSV54159059; called by muse, mutect2, varscan2
- MAPK8IP2 | c.172-69C>T | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99151242; called by muse, varscan2
